Somatic mutation profile of tumor specimen 0DOG3F from CCDI case PBCCBA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 17.1 years (6,264 days).
Specimen 0DOG3F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb4de62c-90e0-498a-a0e5-76ea64eb37bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOG2V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5161ad32-7e5c-4aef-a27e-0c39801b8346

The open-access MAF lists 45 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 14, Nonsense Mutation 4, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 216/692 reads (31%) | catalogued as rs886041791, COSV99967848; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 67/341 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GALC | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 238/840 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770485731, CM970561, COSV54331047; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5902C>T p.R1968* (on ENST00000358273 / NM_001042492.3; = p.R1947* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 81/788 reads (10%) | catalogued as rs137854552, CM900173, COSV62199973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1638G>T p.Q546H | Missense Mutation (SNP) | VAF 106/1296 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1057519940, COSV55883555, COSV55928679, COSV55957396; ClinVar: likely pathogenic; called by muse, mutect2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 65/479 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ANKRD11 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 22/167 reads (13%) | catalogued as CM158521, COSV56356166; called by muse, mutect2, varscan2
- ANKRD24 | c.3082C>T p.R1028W | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1177823872, COSV53667594; called by muse, mutect2, varscan2
- ASB3 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 126/858 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs767347896, COSV99711849; called by muse, mutect2, varscan2
- ATP2A3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs138857372; called by muse, mutect2, varscan2
- CFAP92 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.225); catalogued as rs754077147; called by muse, mutect2, varscan2
- CSMD2 | c.9584C>T p.T3195M | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs180811686; called by muse, mutect2, varscan2
- EIF1AX | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 260/366 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63309369; called by muse, mutect2, varscan2
- EMP1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 77/542 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99916924; called by muse, mutect2, varscan2
- EPX | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.323); catalogued as rs756362103, COSV56598674; called by muse, mutect2, varscan2
- IL17RE | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 82/504 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.024); catalogued as rs780247234; called by muse, mutect2, varscan2
- MIP | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs767456401, COSV99234265; called by muse, mutect2, varscan2
- MRGPRX3 | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs758327883; called by muse, mutect2, varscan2
- NF1 | c.3974G>A p.R1325K | Missense Mutation (SNP) | VAF 111/669 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as CM153417, CS072251, COSV62225257; called by muse, mutect2, varscan2
- PIK3CA | c.1097C>G p.P366R | Missense Mutation (SNP) | VAF 78/810 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as COSV55877027, COSV55880064, COSV55994474; called by muse, mutect2
- SETD2 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 170/589 reads (29%) | catalogued as COSV100339590; called by muse, mutect2, varscan2
- TRMT10A | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 78/1213 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as rs543833042, COSV56744953; called by muse, mutect2
- WDR97 | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868705777; called by muse, mutect2
- BCOR | c.3225_3228del p.N1075Kfs*37 | Frame Shift Del (DEL) | VAF 86/124 reads (69%) | called by mutect2, varscan2
- CHRNA5 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 61/607 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- EYS | c.5801T>C p.F1934S | Missense Mutation (SNP) | VAF 93/746 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRFIP1 | c.2126G>A p.G709D (on ENST00000392000 / NM_001137552.2; = p.G685D on NM_004735.4) | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MBD6 | c.748G>C p.A250P | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MYOCD | c.1569G>C p.E523D | Missense Mutation (SNP) | VAF 41/577 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGAP28 | c.1789T>C p.L597= (on ENST00000383472 / NM_001366230.1; = p.L438= on NM_001010000.3) | Silent (SNP) | VAF 49/770 reads (6%) | called by muse, mutect2
- ARHGEF18 | c.2202C>T p.S734= (on ENST00000359920 / NM_001130955.2; = p.S630= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV60472660; called by muse, varscan2
- C4orf19 | c.360G>A p.R120= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- CALCOCO1 | c.765A>G p.R255= | Silent (SNP) | VAF 52/672 reads (8%) | called by muse, mutect2
- CRACD | c.1014C>T p.D338= | Silent (SNP) | VAF 54/279 reads (19%) | catalogued as rs1403508866, COSV99948331; called by muse, mutect2, varscan2
- FAM83B | c.492A>G p.K164= | Silent (SNP) | VAF 61/1188 reads (5%) | called by muse, mutect2
- FTHL17 | c.9C>T p.T3= | Silent (SNP) | VAF 55/77 reads (71%) | catalogued as rs774744538, COSV63266625; called by muse, mutect2, varscan2
- H3C4 | c.243T>G p.T81= | Silent (SNP) | VAF 25/503 reads (5%) | called by muse, mutect2
- LTBP4 | c.4644C>T p.C1548= (on ENST00000308370 / NM_001042544.1; = p.C1511= on NM_003573.2) | Silent (SNP) | VAF 30/186 reads (16%) | catalogued as rs1434334944, COSV52576666; called by mutect2, varscan2
- PFKFB4 | c.546C>T p.R182= | Silent (SNP) | VAF 36/298 reads (12%) | catalogued as rs529835629; called by muse, varscan2
- PLEC | c.6537C>T p.A2179= (on ENST00000322810 / NM_201380.4; = p.A2069= on NM_000445.5) | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs782420032; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINF1 | c.177C>T p.S59= | Silent (SNP) | VAF 60/175 reads (34%) | called by muse, mutect2, varscan2
- SLC26A8 | c.2103G>A p.A701= | Silent (SNP) | VAF 69/196 reads (35%) | catalogued as rs548161476; called by muse, mutect2, varscan2
- SPTY2D1 | c.1230A>G p.R410= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs937330402; called by muse, mutect2, varscan2
- ADGRG5 | c.546+14C>T | Intron (SNP) | VAF 40/113 reads (35%) | catalogued as rs754271937, COSV61083095; called by muse, mutect2, varscan2
- CFAP410 | c.545+79C>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
